Surgical pathology report (de-identified scan), TCGA case TCGA-US-A77G, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Garvan Institute of Medical Research, specimen TCGA-US-A77G-01A (Primary Tumor).

[page 1 of 4]
UUID:FB498A85-B151-4963-BA96-ASBF955310C0

ICD-O-3
Adenocarcinoma, duct NOS
8500/3
Site: Overlapping lesion of
pancreas (head/body)
C25.0
y/d 8/20/13

RECEIVED:

REPORTED:

CLINICAL NOTES:

Pancreatic head mass ? pancreatic cancer.

SPECIMEN:
WHIPPLE'S

MACROSCOPIC -

The posterior portal vein margin has been inked blue. Neck margin is inked black. Around the distal part of the common bile duct is tumour measuring up to 15mm and present at 20mm from the ampulla of Vater and 20mm from the common bile duct margin.

1. SPECIMEN TYPE:

The specimen comprises a partial pancreatectomy (Whipple's resection).

2. SPECIMEN DIMENSIONS:

Length of duodenum: 110mm.

Length of lesser curve of stomach: 70mm.

Length of greater curve of stomach: 70mm.

Size of gallbladder: 60 x 60 x 120mm.

Wall thickness of gallbladder: 3mm.

Calculi in gallbladder: present.

Size of and weight of spleen: N/A.

Length of bile duct: 80mm.

Maximum diameter of bile duct: 10mm.

Size of pancreas: 100mm from medial to lateral, 80mm from superior to inferior and 50mm from anterior to posterior.

Location of stent: Present - plastic in the distal common duct and protruding out into the duodenum.

3. TUMOUR LOCATION:

Pancreatic body/pancreatic head.

4. TUMOUR:

Configuration: infiltrative.

Description: pale, firm with an ill defined margin.

5. TUMOUR SIZE:

Greatest dimension: 15mm.

*Additional dimensions: 15 x 15mm.

REVIEWING DOCTOR'S SIGNATURE: _____ DATE: _____

[page 2 of 4]
6. (MACROSCOPIC) DISTANCE OF TUMOUR TO MARGINS:

Pancreatic neck: 10mm.
Periuncinate soft tissue: 40mm.
Posterior retroperitoneal: 2-3mm.
Portal vein bed: 2-3mm.
Anterior pancreatic capsule: 10mm.
Common bile duct: possibly involved.
Proximal intestinal/gastric: 85mm.
Distal intestinal margin: 180mm.
Proximal pancreatic margin (applicable to distal pancreatectomies only): N/A.

7. ADDITIONAL GROSS PATHOLOGIC FINDINGS:

Chronic pancreatitis: present.
Chronic cholecystitis and cholelithiasis: present.
Acute pancreatitis: negative.
Pancreatic calculi: negative.
Stomach: nil significant.
Intestine: nil significant.
Common bile duct obstruction: a stent is in situ.
Pancreatic duct obstruction: present with dilatation.

BLOCK KEY: 1= ex frozen of the pancreatic margin. 2=ex frozen of the pancreatic lesion.
3,4,5+6=Specimen serially sectioned and submitted in entirety transverse sections through mid common bile duct within head of pancreas from distal to proximal with surrounding tumour and adjacent portal vein margin and distal cystic duct. 7-10=representative transverse sections adjacent common bile duct and neck margins. 11+12=representative from anterior body of pancreas with pancreatitis. 13+14=longitudinal section through ampulla of Vater. 15=representative posterior uncinate process adjacent to tumour. 16=representative from uninvolved body of pancreas without macroscopic pancreatitis. 17=proximal common bile duct margin, also included a single cystic duct node. 18=neck of gallbladder representative. 19=body of gallbladder including scarred area. 20=fundus of gallbladder representative. 21=proximal gastric margin. 22=pylorus. 23=representative distal small bowel margin. 24=multiple nodes from lesser curve. 25=representative from greater curve. 26=single anterior pancreatic node. 27=multiple nodes from posterior peripancreatic fat.

INTRA-OPERATIVE FROZEN SECTION REPORT:

- *1. Neck Margin: No Evidence of malignancy.
- *2 Tumour: Moderately differentiated adenocarcinoma > 75% plus vessel.

Reported by

MICROSCOPIC -

Sections of the tumour confirm a well to moderately differentiated ductal carcinoma arising in the posterior body/neck adjacent to the mid to distal common bile duct (CBD). The overall tumour dimensions are 20 x 20 x 20mm. The tumour spreads alongside the mid common bile duct (with a common bile duct margin of 10mm). Tumour shows a gland and ductal architecture with marked desmoplasia and extensive perineural infiltration. There is extensive perineural invasion and spread into the peripancreatic tissue. Tumour invades the wall of the portal vein (Block 3) but does not reach the lumen or involve the peripheral venous resection margin. The tumour comes to within 1mm of the posterior soft tissue margin at the neck of pancreas (blocks 4 and 7) Lymphovascular space invasion is noted (Blocks 4) with extension into a peripancreatic node (Block 8) with a micrometastasis in a peripancreatic node (Block 4) and periuncinate node (block 15). Adjacent to the tumour high grade PanIN is identified (block 8).

REVIEWING DOCTOR'S SIGNATURE: _____ DATE: _____

[page 3 of 4]
Sections from the pancreatic neck resection margin show chronic pancreatitis. No high grade PanIN is identified. Sections from the proximal common bile duct margin show no evidence of malignancy and uninvolved cystic duct node.

Representative sections from the ampulla of Vater show reactive changes within the common bile duct epithelium along with some epithelial hyperplasia. Representative sections from the pancreas elsewhere show normal morphology of ducts without PanIN. Fatty infiltration of the pancreas is seen in Blocks 11 & 12 with associated fat necrosis. Representative sections from the gallbladder show Rokitsansky-Aschoff sinus formation with fibrosis of the gallbladder wall and a mixed inflammatory cell infiltrate. The gallbladder mucosa is attenuated and shows underlying haemorrhage. Cholesterosis is not identified. Representative sections from the proximal gastric margin are within normal limits. Representative sections from the pylorus are within normal limits. Representative sections from the distal small bowel margin are also within normal limits.

Three out of eight peripancreatic nodes contain tumour (including the one seen in Block 4 and including the one seen in Block 8 and block 15). No lesser curve nodes are identified. Only one single lymphoid aggregate is noted from the greater curve. There are two cystic duct nodes. This gives a total of three out of eleven nodes involved.

CONCLUSION :

8. **TUMOUR LOCATION:**
BODY/NECK OF PANCREAS
9. **HISTOLOGIC TYPE:**
DUCTAL CARCINOMA
10. **HISTOLOGIC GRADE:**
MODERATELY DIFFERENTIATED
11. **TUMOUR SIZE:**
20 X 20 X 20.
12. **EXTENSION OUT OF PANCREAS:**
POSTERIORLY
13. **SMALL VESSEL (CAPILLARY/LYMPHATIC) INVASION:**
PRESENT.
14. **LARGE VESSEL (VEIN/ARTERY) INVASION:**
PRESENT BUT NOT INTO LUMEN
15. **PERINEURAL INVASION:**
PRESENT AND EXTENSIVE

16. **(MICROSCOPIC) DISTANCE OF INVASIVE TUMOUR FROM RESECTION MARGINS:**
Pancreatic neck: 5mm
Periuncinate soft tissue: Greater than 10mm
Posterior retroperitoneal: 1mm
Portal vein bed: 1mm
Common bile duct: 10mm

17. **LYMPH NODES FROM MAIN RESECTION SPECIMEN:**
Separately received lymph nodes: ELEVEN

18. **Pan-IN:**
Highest grade of Pan-In present: High grade
Grade of Pan-In at pancreatic neck resection margin: Not applicable

REVIEWING DOCTOR'S SIGNATURE: _____ DATE: _____

[page 4 of 4]
19. PATHOLOGIC STAGING (pTNM, AJCC 6th edition 2002)

Staged as: Pancreatic ductal carcinoma

pT: 3

pN: 1

pM: X

Overall stage: STAGE IIB

Additional pathologic comments and findings in other resected organs:

SPECIFIC OTHER FINDINGS

Immunohistochemistry (ampullary and periampullary tumours only)

CK7: not applicable

CK20: not applicable

CDX2: not applicable

SUMMARY -

Tumour type: DUCTAL ADENOCARCINOMA

Tumour grade: MODERATELY DIFFERENTIATED

Tumour location: BODY NECK OF PANCREAS

Tumour size: 20 X 20 X 20MM

Lymph nodes: 3 OUT OF 11

Involved or close margins (includes tumour less than 1mm from margin): POSTERIOR SOFT TISSUE AND PORTAL VEIN.

PATHOLOGIST:

OFFICE USE ONLY

• CHARGE:

• CLASS:

• SUMMARY:

• REPORTER:

• CUTUP:

• TYPIST:

DUCTAL ADENOCARCINOMA, LYMPH NODE METS

T3 pN1 MX, AT LEAST STAGE IIB

REVIEWING DOCTOR'S SIGNATURE: _____ DATE: _____

Source: NCI Genomic Data Commons file 27ecae30-41c3-417a-a252-d47dd423d01d (TCGA-US-A77G.FB498A85-B151-4963-BA96-A5BF955310C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).